Somatic mutation profile of tumor specimen TARGET-10-PARAKF-03A (aliquot TARGET-10-PARAKF-03A-01D) from TARGET case TARGET-10-PARAKF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.4 years (3,051 days).
Specimen TARGET-10-PARAKF-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6796af1f-a640-465d-aeda-2adb6ceb3f5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARAKF-10A (Blood Derived Normal), aliquot TARGET-10-PARAKF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8c31773-429e-4d32-98f7-0dfe3dfc2ba8

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 15, Silent 9, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 66/354 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- CACNA1B | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs202024500, COSV53121757; called by muse, mutect2
- CDHR1 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 55/121 reads (45%) | catalogued as rs191858417, CM156177, COSV60559927; called by muse, mutect2, varscan2
- DSCAM | c.5624C>A p.P1875H | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68021936; called by muse, mutect2, varscan2
- FSTL4 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs780854028; called by muse, varscan2
- GOLGA6A | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs542174200, COSV51804412; called by muse, mutect2, varscan2
- GPR156 | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs748614322, COSV59938308; called by muse, mutect2, varscan2
- MLPH | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.165); catalogued as rs372579688, COSV99222543; called by muse, mutect2, varscan2
- OR4P4 | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV58920860; called by muse, mutect2, varscan2
- PCDHA6 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.259); catalogued as COSV67034078, COSV67044410; called by muse, mutect2, varscan2
- PCDHB4 | c.534C>A p.H178Q | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.97); catalogued as COSV52019999; called by muse, mutect2, varscan2
- RP1 | c.902C>A p.A301D | Missense Mutation (SNP) | VAF 93/256 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV55111361; called by muse, mutect2, varscan2
- SNTB1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs753694409, COSV67324796; called by muse, mutect2, varscan2
- SPARC | c.732C>T p.D244= | Splice Region (SNP) | VAF 15/106 reads (14%) | catalogued as rs758034123, COSV50557814; called by muse, mutect2, varscan2
- DHTKD1 | c.2257A>T p.M753L | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.267); called by muse, mutect2
- EDEM1 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2
- TRBV20-1 | c.331A>G p.R111G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.085); called by mutect2, varscan2
- ATP8A2 | c.1290T>G p.T430= | Silent (SNP) | VAF 224/714 reads (31%) | catalogued as COSV54939630; called by muse, mutect2, varscan2
- ELAVL2 | c.813C>T p.H271= | Silent (SNP) | VAF 62/162 reads (38%) | catalogued as COSV56358160; called by muse, mutect2, varscan2
- HLTF | c.354T>G p.A118= | Silent (SNP) | VAF 44/465 reads (9%) | catalogued as COSV59499107; called by muse, mutect2
- PCDHA4 | c.2118G>A p.A706= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs782718692, COSV63539392; called by muse, varscan2
- PCDHGB5 | c.501G>T p.L167= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV53908029; called by muse, mutect2, varscan2
- PGAP2 | c.186G>A p.S62= (on ENST00000463452 / NM_001346398.2; = p.S123= on NM_014489.4) | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs754872436, COSV53464202; called by muse, mutect2, varscan2
- SLC17A7 | c.498C>T p.R166= | Silent (SNP) | VAF 58/134 reads (43%) | catalogued as COSV55546745, COSV99677069; called by muse, mutect2, varscan2
- SOX6 | c.1191G>A p.T397= (on ENST00000528429 / NM_001145819.2; = p.T356= on NM_017508.3) | Silent (SNP) | VAF 233/467 reads (50%) | catalogued as rs139974161, COSV57044852; called by muse, mutect2, varscan2
- UNC80 | c.4995G>T p.G1665= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as rs889568408, COSV55884649; called by muse, mutect2, varscan2
